Somatic mutation profile of cancer-model specimen HCM-STAN-0840-C49-85A (3D Organoid, passage 4; aliquot HCM-STAN-0840-C49-85A-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-STAN-0840-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 67.4 years (24,606 days).
Specimen HCM-STAN-0840-C49-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e19ec56c-f6c1-4aed-80fb-8eacdf9e3f72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0840-C49-10A (Blood Derived Normal), aliquot HCM-STAN-0840-C49-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcd62f85-8e58-4038-a936-a0e2e342b735

The open-access MAF lists 97 somatic variants for this specimen: 75 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 19, Nonsense Mutation 7, Intron 2, Splice Site 2, In Frame Ins 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL5 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 591/1275 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs752604368; called by muse, mutect2, varscan2
- ADORA3 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs767963822; called by muse, mutect2, varscan2
- ANKRD34B | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 182/402 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432029689; called by muse, mutect2, varscan2
- ATG9B | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 139/1811 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs762679491; called by muse, mutect2
- CADM1 | c.146C>G p.T49R | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59005301; called by muse, mutect2, varscan2
- FOXI3 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 22/527 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1427389100, COSV67916788; called by muse, mutect2
- HERC1 | c.14072G>A p.R4691Q | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757446033; called by muse, mutect2, varscan2
- HLA-A | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 386/810 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs199474396; called by muse, mutect2, varscan2
- HNF4G | c.614G>A p.R205H (on ENST00000354370 / NM_001330561.2; = p.R252H on NM_004133.5) | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs767200428, COSV62967554, COSV62972655; called by muse, mutect2, varscan2
- IGFBP2 | c.64_65insCGCTGC p.L21_L22insPL | In Frame Ins (INS) | VAF 7/133 reads (5%) | catalogued as rs1461501999; called by mutect2, pindel
- INAVA | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1394611016, COSV66256314; called by muse, mutect2, varscan2
- ITPRID1 | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 107/682 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs549350333; called by muse, varscan2
- KCNA4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 377/377 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs777488025, COSV100068823; called by muse, mutect2, varscan2
- KLHL6 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 399/399 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375261661, COSV58064866; called by muse, mutect2, varscan2
- KRTAP5-3 | c.581G>C p.C194S | Missense Mutation (SNP) | VAF 308/754 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs527598636, COSV68790660; called by mutect2, varscan2
- LMNA | c.1898G>A p.G633E | Missense Mutation (SNP) | VAF 317/663 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.672); catalogued as rs1363694601; called by muse, mutect2, varscan2
- MASP1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 332/333 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs766084598, COSV51461074; called by muse, varscan2
- MCOLN1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 114/616 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs770521266; called by muse, mutect2, varscan2
- MRPS12 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 346/1094 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs761146514, COSV99671408; called by muse, mutect2, varscan2
- NOMO2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 27/527 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1434817012; called by muse, mutect2
- OR8K5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756900844, COSV57889897, COSV57889909; called by muse, mutect2, varscan2
- RNMT | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766060545; called by muse, mutect2, varscan2
- RUNX1T1 | c.1423G>T p.A475S (on ENST00000265814 / NM_001198628.1; = p.A448S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/539 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56139494; called by muse, mutect2, varscan2
- SHKBP1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 399/1188 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs762560064, COSV52543651; called by muse, mutect2, varscan2
- SYT6 | c.829C>T p.R277C (on ENST00000610222 / NM_001366225.1; = p.R192C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 400/400 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs202111489; called by muse, mutect2, varscan2
- THSD7A | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 451/962 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70264148, COSV70268650; called by muse, mutect2, varscan2
- TMEM121 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 400/2259 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1236401840, COSV66796801; called by muse, mutect2, varscan2
- TP53 | c.999del p.R335Vfs*10 | Frame Shift Del (DEL) | VAF 310/429 reads (72%) | catalogued as COSV53129285; called by mutect2, pindel, varscan2
- TPM3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1407215498; called by muse, mutect2, varscan2
- ZNF100 | c.1454A>G p.Y485C | Missense Mutation (SNP) | VAF 257/556 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1312668572; called by muse, mutect2, varscan2
- ZNF214 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs139112669; called by muse, mutect2, varscan2
- ZNF407 | c.2486A>G p.K829R | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs775166972; called by muse, mutect2, varscan2
- ZNF491 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 173/832 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs752262629, COSV60057822; called by muse, mutect2, varscan2
- ZNF521 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 348/349 reads (100%) | catalogued as COSV64125592, COSV99052392; called by muse, mutect2, varscan2
- ADGRF4 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ATP7B | c.3837C>A p.D1279E | Missense Mutation (SNP) | VAF 52/680 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CCSER1 | c.2618T>C p.L873S | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.8347T>C p.F2783L (on ENST00000297405 / NM_001363185.1; = p.F2614L on NM_052900.3) | Missense Mutation (SNP) | VAF 386/387 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAJC16 | c.2060A>G p.K687R | Missense Mutation (SNP) | VAF 215/477 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FASTKD2 | c.509T>G p.L170* | Nonsense Mutation (SNP) | VAF 14/473 reads (3%) | called by muse, mutect2
- GABRG3 | c.1315T>G p.L439V | Missense Mutation (SNP) | VAF 365/366 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GLT6D1 | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 445/668 reads (67%) | SIFT tolerated (0.71); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GOLGA1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 188/660 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPLD1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- GRXCR1 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 462/462 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPKC | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 166/674 reads (25%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2757G>C p.Q919H | Missense Mutation (SNP) | VAF 172/785 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, varscan2
- KALRN | c.5826del p.D1943Tfs*14 (on ENST00000360013 / NM_001024660.4; = p.D246Tfs*14 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 276/382 reads (72%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.822-7_824del p.X274_splice | Splice Site (DEL) | VAF 66/182 reads (36%) | called by pindel, varscan2
- KLHL12 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 235/513 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT8 | c.862_864dup p.E288dup | In Frame Ins (INS) | VAF 201/484 reads (42%) | called by mutect2, pindel, varscan2
- KRTAP26-1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 31/547 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.456); called by muse, mutect2
- LCORL | c.5255C>G p.P1752R | Missense Mutation (SNP) | VAF 69/74 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL5 | c.592-15_600del p.X198_splice | Splice Site (DEL) | VAF 25/120 reads (21%) | called by mutect2, pindel, varscan2
- MMRN1 | c.2192C>A p.T731K | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MUC5B | c.14756C>A p.S4919Y | Missense Mutation (SNP) | VAF 317/698 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MYO5B | c.2359C>A p.L787M | Missense Mutation (SNP) | VAF 186/483 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKX2-4 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 26/790 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NWD1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 216/880 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- OBP2A | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 17/868 reads (2%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OGFOD2 | c.484C>T p.Q162* (on ENST00000228922 / NM_001304833.1; = p.Q102* on NM_024623.3) | Nonsense Mutation (SNP) | VAF 343/344 reads (100%) | called by muse, varscan2
- PMS1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 259/259 reads (100%) | called by muse, mutect2, varscan2
- RBM25 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- SETBP1 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 450/450 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by mutect2, varscan2
- SLC36A2 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPTBN5 | c.9881A>C p.E3294A | Missense Mutation (SNP) | VAF 845/845 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SUPT6H | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 263/264 reads (100%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TERF1 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 508/520 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- TNRC6B | c.5051G>T p.G1684V (on ENST00000454349 / NM_001162501.2; = p.G1574V on NM_015088.3) | Missense Mutation (SNP) | VAF 191/449 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRRAP | c.4847T>C p.L1616P (on ENST00000359863 / NM_001244580.1; = p.L1598P on NM_003496.3) | Missense Mutation (SNP) | VAF 218/1000 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by mutect2, varscan2
- ULK4 | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 82/202 reads (41%) | called by muse, mutect2, varscan2
- UTP3 | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 396/396 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF426 | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 209/793 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF608 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF782 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AMER3 | c.570G>A p.P190= | Silent (SNP) | VAF 535/536 reads (100%) | catalogued as rs1262658400, COSV58468055; called by muse, mutect2, varscan2
- ANO1 | c.1089C>T p.N363= | Silent (SNP) | VAF 125/278 reads (45%) | called by muse, mutect2, varscan2
- BCKDHB | c.678G>A p.L226= | Silent (SNP) | VAF 130/130 reads (100%) | catalogued as COSV57519289; called by muse, mutect2, varscan2
- CELSR1 | c.6678C>T p.N2226= | Silent (SNP) | VAF 840/842 reads (100%) | catalogued as rs776184322; called by muse, mutect2, varscan2
- CEP250 | c.3066G>A p.Q1022= | Silent (SNP) | VAF 139/371 reads (37%) | catalogued as rs767563913; called by muse, mutect2, varscan2
- CFAP46 | c.2217C>T p.N739= | Silent (SNP) | VAF 450/450 reads (100%) | catalogued as rs751927014, COSV63949636; called by muse, mutect2, varscan2
- DNAH10 | c.3777A>C p.A1259= (on ENST00000409039; = p.A1198= on NM_207437.3) | Silent (SNP) | VAF 363/363 reads (100%) | called by muse, mutect2, varscan2
- IDUA | c.1911G>A p.P637= | Silent (SNP) | VAF 616/616 reads (100%) | catalogued as rs780005721, COSV99925588; called by muse, mutect2, varscan2
- JCAD | c.1104C>T p.G368= | Silent (SNP) | VAF 165/468 reads (35%) | catalogued as rs761072255; called by muse, mutect2, varscan2
- KRTAP5-3 | c.582T>C p.C194= | Silent (SNP) | VAF 312/746 reads (42%) | catalogued as rs879128934, COSV68790573; called by mutect2, varscan2
- MYBPC2 | c.1527G>A p.T509= | Silent (SNP) | VAF 184/624 reads (29%) | catalogued as rs200711489; called by muse, mutect2, varscan2
- PAX1 | c.1374T>A p.S458= | Silent (SNP) | VAF 20/716 reads (3%) | called by muse, mutect2
- PMIS2 | c.42C>T p.N14= | Silent (SNP) | VAF 357/592 reads (60%) | catalogued as rs553780461; called by muse, mutect2
- PTEN | c.708C>T p.D236= | Silent (SNP) | VAF 38/38 reads (100%) | catalogued as rs1183182915, COSV99057988; ClinVar: likely benign; called by muse, varscan2
- SPRR4 | c.237G>A p.K79= | Silent (SNP) | VAF 11/305 reads (4%) | catalogued as rs1345501801; called by muse, mutect2
- STARD9 | c.3436C>T p.L1146= | Silent (SNP) | VAF 19/588 reads (3%) | catalogued as rs1256735815; called by muse, mutect2
- TOR2A | c.339C>T p.G113= | Silent (SNP) | VAF 626/1075 reads (58%) | catalogued as rs769723614, COSV59127046; called by muse, mutect2, varscan2
- TTN | c.27027A>T p.G9009= (on ENST00000591111; = p.G8082= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 194/384 reads (51%) | called by muse, mutect2, varscan2
- ZNF558 | c.969C>T p.N323= | Silent (SNP) | VAF 392/846 reads (46%) | catalogued as rs73491457; called by muse, mutect2, varscan2
- NBPF9 | c.2476+1594G>T | Intron (SNP) | VAF 92/334 reads (28%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5619C>T | Intron (SNP) | VAF 193/454 reads (43%) | catalogued as rs878898338, COSV100663891; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26674109 C>A | 3'Flank (SNP) | VAF 153/289 reads (53%) | called by muse, mutect2, varscan2
